Surgical pathology report (de-identified scan), TCGA case TCGA-HD-7832, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-7832-01A (Primary Tumor).

[page 1 of 4]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

Final Diagnosis (Verified)

Lateral floor of mouth, resection including partial mandibulectomy and glossectomy, with multiple frozen sections:

Moderately-differentiated keratinizing invasive squamous cell carcinoma of right lateral floor of mouth.

Tumor size: 5.3 cm in greatest dimension.

The tumor invades through the anterior mandible and into the subcutaneous soft tissue.

Margins: All margins are negative for tumor.

- Soft tissue overlying anterior mandible: The tumor is 0.5 cm away from this margin.
- Posterior soft tissue: The tumor is 0.5 cm away from this margin.
- Inferior soft tissue: The tumor is 0.8 cm away from this margin.
- Right soft tissue: The mucosal and deep soft tissue margins are free of tumor.
- Right mandible: No tumor identified.
- Left soft tissue: No tumor identified.
- Left mandible: No tumor identified.

AJCC pathologic stage: pT4a pN0.

Right level 1A, 1B lymph nodes:

Five (5) lymph nodes are identified, and all are negative for tumor.

Right level 2A, 3 lymph nodes:

Fourteen (14) lymph nodes are identified, and all are negative for tumor.

Printed by:
Printed on:

[page 2 of 4]
Surg Path Final Report

* Final Report *

Left level 1B lymph nodes:

Six (6) lymph nodes are identified, and all are negative for tumor.

Left level 2A lymph nodes:

Five (5) lymph nodes are identified, and all are negative for tumor.

Left level 3 lymph nodes:

Five (5) lymph nodes are identified, and all are negative for tumor.

Signature Line

Gross Description (Verified)

"FSA1." All frozen section control tissue is submitted in "FSA1".

"FSA2." All frozen section control tissue is submitted in "FSA2".

"NFA." The specimen consists of a 10.5 x 9 x 5.7 cm resection to include anterior aspect of mandible, tongue, inferior oral cavity and attached soft tissue. The specimen has been partially inked by the pathologist as follows: posterior/deep margin = blue; inferior margin = black. The remaining specimen will be inked as follows: left soft tissue and bone margin = orange; tumor = yellow; anterior soft tissue margin = green. A special section of the right soft tissue/mucosal margin is submitted with the margin inked black, and labeled A12. Representative sections of the posterior/deep margin and inferior margin have previously been submitted for frozen section. On sectioning, there is a 3.7 cm (anterior to posterior) x 3.4 cm (superior to inferior) x 5.3 cm (left to right) soft tan-white mass which comes to within 0.5 cm of the posterior/deep margin, 0.3 cm of the inferior margin, and 1.5 cm of the left soft tissue margin. The mass grossly appears to erode completely through the anterior mandible and into subcutaneous tissue. The mass does not grossly appear to involve the anterior aspect of the tongue. No additional masses or areas of interest are grossly identified. "A1," mass with adjacent posterior/deep soft tissue margin; "A2," mass with adjacent inferior soft tissue margin; "A3," left soft tissue margin; "A4," right soft tissue/tumor; "A5," anterior mucosal margin; "A6," left mandible margin; "A7," right mandible margin; "A8," mass eroding into mandible; "A9," mass with adjacent tongue; "A10-A11," mass; "A12," true right soft tissue margin.

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Surg Path Final Report

* Final Report *

"Right level 1A, 1B." The specimen consists of a 5.2 x 5 x 3 cm portion of soft yellow-gray tissue. On sectioning, a 3.2 x 2.3 x 1.5 cm salivary gland is identified. This has a yellow lobulated cut surface. On further examination, five possible lymph nodes are identified. These range in size from 0.6 – 1.9 cm. "B1-B2," lymph nodes; "B3," salivary gland, representative.

"Right level 2A and 3." The specimen consists of a 5 x 4.8 x 2.5 cm aggregate of soft yellow-gray tissue. On sectioning, fourteen possible lymph nodes are identified. These range in size from 0.3 – 1.6 cm. "C1-C3," fragments, representative.

"Left level 1B." The specimen consists of a 6 x 4.2 x 2.5 cm portion of soft yellow-gray tissue. On sectioning, a 3.5 x 2.7 x 1.5 cm salivary gland is identified. This has a yellow-tan lobulated cut surface. On further examination, six possible lymph nodes are identified. These range in size from 0.3 – 1.1 cm. "D1-D2," lymph nodes; "D3," salivary gland, representative.

"Left level 2A." The specimen consists of a 6.7 x 4.4 x 1.8 cm aggregate of soft yellow-gray tissue. On sectioning, five possible lymph nodes are identified. These range in size from 0.3 – 1.6 cm. "E1-E2," fragments, representative.

"Left level 3." The specimen consists of a 3.1 x 2.8 x 1.5 cm aggregate of soft yellow-gray tissue. On sectioning, five possible lymph nodes are identified. These range in size from 0.4 – 1 cm. "F," 5p, representative.

Received for research purposes is one yellow cassette labeled

ADDITIONAL TISSUE REQUESTED

SEND ADD SLIDE TO

Additional section of right margin submitted in cassette "A12."

Signature Line

Frozen Section Diagnosis (Verified)

History: Oral cancer.

Mandible, mandibulectomy:

Gross: Posterior surface inked blue, inferior black.

Representative sections taken from these surfaces.

FSA1: Negative for tumor (posterior margin).

FSA2: Negative for tumor (inferior margin).

NOTE: Small portion of tumor submitted to tissue bank.

Clinical Information (Verified)

Floor of mouth squamous cell carcinoma.

Completed Action List:

Printed by:

Printed on:

[page 4 of 4]
Surg Path Final Report

* Final Report *

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 74b480da-4808-4fe6-83cf-a27ee72fdc87 (TCGA-HD-7832.A8771FF3-4678-4A51-B535-23FD2BE129E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).